Gene-level copy-number profile of tumor specimen TCGA-B6-A0IM-01A from TCGA case TCGA-B6-A0IM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 75.4 years (27,557 days).
Specimen TCGA-B6-A0IM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.a12ef456-3010-4ec9-a428-0259be208606.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0IM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a8c01f31-38d3-4590-87c2-19ead1f546f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,393; copy number 2: 43,276; copy number 3: 10,625; copy number 4: 195; copy number 5: 118; copy number 6: 14; copy number 7: 195.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0IM-01A-11D-A036-01): tumor purity 0.78, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 327 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,335,514, 14 genes, copy number 6: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.
- chr8:34,784,028–43,674,591, 195 genes, copy number 7 (broad region; genes not listed).
- chr14:22,011,910–22,506,702, 68 genes, copy number 5 (broad region; genes not listed).
- chr15:69,278,328–69,298,795, 1 gene, copy number 5 (within-gene range 3–5): AC026992.2.
- chr15:69,298,912–70,198,509, 17 genes, copy number 5: PAQR5, AC027237.4, AC027237.3, Y_RNA, KIF23, AC027237.1, RPLP1, U3, AC027237.2, DRAIC, AC100826.1, GEMIN8P1, AC021818.1, TLE3, MIR629, RNU6-745P, AC026583.1.
- chr15:72,041,194–72,475,168, 18 genes, copy number 5 (within-gene range 3–5): EIF5A2P1, RNU2-65P, SENP8, AC020779.1, AC020779.2, GRAMD2A, PKM, PARP6, AC009690.3, AC009690.2, CELF6, AC009690.1, HEXA, HEXA-AS1, RPL12P35, TMEM202, TMEM202-AS1, PHBP20.
- chr15:89,784,895–90,082,206, 14 genes, copy number 5 (within-gene range 3–5): ANPEP, AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3, ZNF710, MIR3174, AC087284.1.

Autosomal genes at a single copy (total copy number 1): 5,393. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
